Surgical pathology report (de-identified scan), TCGA case TCGA-19-1786, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-1786-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Addendum Present

FINAL DIAGNOSIS

A. LEFT FRONTAL LOBE OF BRAIN, MASS, BIOPSY:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

TCGA-19-1786

B. SPECIMEN LABELED "PERMANENT EDGE", BIOPSY:
-- GLIOBLASTOMA MULTIFORME

C. SPECIMEN LABELED "PERMANENT CORE", BIOPSY:
-- GLIOBLASTOMA MULTIFORME

D. LEFT FRONTAL NEOPLASM, CORE, BIOPSY:
-- MALIGNANT GLIOMA DEMONSTRATING OLIGODENDROGLIAL DIFFERENTIATION.

E. SPECIMEN LABELED "EDGE", BIOPSY:
-- INFILTRATING GLIOMA DEMONSTRATING OLIGODENDROGLIAL DIFFERENTIATION.

F. SPECIMEN LABELED PERMANENT WHITE MATTER, BIOPSY:
-- INFILTRATING GLIOMA DEMONSTRATING ASTROCYTIC DIFFERENTIATION.

Electronically Signed Out By By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A: Touch Imprint: Glioblastoma.

Addendum/Procedures:

Addendum

Date Ordered:

Date Complete:

Date Reported:

Status: Signed Out

Addendum Diagnosis

Fluorescent in-situ hybridization performed at the [REDACTED] demonstrates losses in chromosome 1p and 19q. A copy of the [REDACTED] report is retained in the Department of Anatomic Pathology files.

Electronically Signed Out By

Clinical History:

left brain tumor

Specimens Submitted As:

A: LEFT FRONTAL MASS

[page 2 of 2]
B: PERMANENT EDGE
C: PERMANENT CORE
D: LEFT FRONTAL NEOPLASM CORE
E: EDGE
F: PERMANENT WM

TCGA-19-1786

Gross Description:

A: Received fresh for intraoperative consultation, labelled with the patient's name and number, and "left frontal mass", are multiple, pink-tan, soft tissue fragments, 3.1 x 1 x 0.5 cm in aggregate. Representative sections are submitted for frozen section and the rest of the specimen is submitted entirely for permanents.

B: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "#4- perm edge", are multiple irregular, pink-tan, soft, cerebriform tissue fragments measuring in aggregate 3.2 x 3.0 x 1.0 cm. Submitted in toto in three cassettes.

C: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "#3-perm core", are multiple irregular, pink-tan, soft, cerebriform tissue fragments measuring in aggregate 2.0 x 1.8 x 0.9 cm. Submitted entirely in one cassette.

D: Received in formalin labeled with the patient's name and number, and "A", is an irregular fragment of opaque white to pink tan, soft, cerebriform tissue measuring 3.2 x 2.0 x 0.9 cm. Submitted entirely in two cassettes.

E: Received in formalin labeled with the patient's name and number, and "B-perm edge", are multiple fragments of opaque white to pale pink tan, soft, cerebriform tissue measuring in aggregate 3.0 x 2.8 x 0.6 cm. Submitted in toto in two cassettes.

F: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "#5-perm WM", are multiple fragments of opaque white to pink tan, soft, cerebriform tissue measuring in aggregate 1.8 x 1.2 x 0.5 cm. Submitted entirely in one cassette.

Summary of Cassettes:

A 1FS
2,3 remainder of the tissue for permanents

Source: NCI Genomic Data Commons file 7bd8096b-b9aa-4959-bad1-866fa8327acf (TCGA-19-1786.6E533C58-E45A-4861-B460-BBE850D2A943.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).